Surgical pathology report (de-identified scan), TCGA case TCGA-61-2000, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2000-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTAL NODULE, EXCISION –
PAPILLARY SEROUS CARCINOMA.

PART 2: OMENTUM, OMENTECTOMY –
PAPILLARY SEROUS CARCINOMA.

PART 3: SMALL BOWEL MESENTERIC IMPLANT, EXCISION –
PAPILLARY SEROUS CARCINOMA.

PART 4: ADNEXA, RIGHT, SALPINGO-OOPHORECTOMY –
A. PAPILLARY SEROUS CARCINOMA INVOLVING RIGHT OVARY.
B. OVARY MEASURES 6.5 CM IN GREATEST DIMENSION.
C. FALLOPIAN TUBE WITH FOCUS OF TUBAL IN-SITU CARCINOMA (see comment).

PART 5: UTERUS, SUPRACERVICAL HYSTERECTOMY –
A. INACTIVE ENDOMETRIUM.
B. MYOMETRIUM WITH MICROSCOPIC HEMANGIOMA.
C. LEFT PARAMETRIAL TISSUE WITH METASTATIC PAPILLARY SEROUS CARCINOMA.

PART 6: SIGMOID COLON AND LEFT ADNEXA, PARTIAL COLECTOMY AND LEFT SALPINGO-OOPHORECTOMY –
A. PAPILLARY SEROUS CARCINOMA, COMPLETELY REPLACING THE LEFT ADNEXA, 10 CM IN GREATEST DIMENSION (see comment).
B. METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING COLONIC SEROSAL SURFACE AND FOCALLY INVOLVING COLONIC MUCOSA.
C. COLONIC MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR.
D. LYMPHOVASCULAR SPACE INVASION IS SEEN.

PART 7: APPENDIX, APPENDECTOMY –
APPENDIX WITH NO SIGNIFICANT PATHOLOGIC CHANGES.

PART 8: RIGHT PELVIC TUMOR, EXCISION –
PAPILLARY SEROUS CARCINOMA.

PART 9: SMALL BOWEL TUMOR IMPLANT, EXCISION –
PAPILLARY SEROUS CARCINOMA.

PART 10: PELVIC TUMOR, EXCISION –
PAPILLARY SEROUS CARCINOMA.

PART 11: RECTAL DONUTS, EXCISION –
UNREMARKABLE COLONIC MUCOSA.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Other: supracervical hysterectomy, bilateral salpino-oophorectomy
TUMOR SIZE:	Maximum dimension: 10 cm
TUMOR TYPE:	Papillary serous carcinoma
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file 65cdb4c3-adcd-497f-aa1c-a0ca6d6e473a (TCGA-61-2000.4E13B897-C34A-4422-9C66-7CA8B2734EF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).